Gene-level copy-number profile of tumor specimen TCGA-K4-A5RI-01A from TCGA case TCGA-K4-A5RI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.4 years (24,614 days).
Specimen TCGA-K4-A5RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d1866f3b-17cb-4066-b551-a57e9e0c4a76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A5RI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/feb8bc5f-cd6d-472a-a6a2-43352c44c296

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 18; copy number 2: 357; copy number 3: 1,342; copy number 4: 24,857; copy number 5: 4,690; copy number 6: 17,677; copy number 7: 6,403; copy number 8: 3,357; copy number 9: 10; copy number 11: 323; copy number 13: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A5RI-01A-11D-A288-01): tumor purity 0.71, ploidy 2.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,165,637–24,088,051, 64 genes (broad region; genes not listed).
- chr10:53,802,771–55,627,942, 1 gene (within-gene range 0–4): PCDH15.
- chr10:54,599,678–56,364,714, 11 genes: NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,043 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,314,500–115,147,288, 1 gene, copy number 9 (within-gene range 6–9): ZBTB20.
- chr3:114,684,580–115,564,389, 9 genes, copy number 9: ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3.
- chr3:156,523,740–173,141,235, 231 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr3:177,441,910–177,767,379, 1 gene, copy number 11 (within-gene range 8–11): LINC00578.
- chr3:177,621,382–182,617,810, 91 genes, copy number 11 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
